Gene-level copy-number profile of tumor specimen C3N-03097-02 from CPTAC case C3N-03097, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen C3N-03097-02: Sample type: Primary Tumor; Tissue type: Tumor; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f2789a15-cb42-40a5-9c99-33edc4a253bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03097-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/82cc9900-e732-41ce-99d5-120c130033b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 761; copy number 2: 23,644; copy number 3: 15,021; copy number 4: 14,416; copy number 5: 5,051; copy number 6: 8.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,703,606–59,703,703, 1 gene (within-gene range 0–2): MIR582.
- chr8:43,246,755–43,247,410, 2 genes: AC022616.5, AC022616.7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,059 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,067,231–79,282,124, 543 genes, copy number 5–6 (broad region; genes not listed).
- chr1:119,000,344–178,038,007, 1,218 genes, copy number 5 (broad region; genes not listed).
- chr3:18,445,024–18,920,401, 1 gene, copy number 5 (within-gene range 4–5): SATB1-AS1.
- chr3:18,954,943–19,702,795, 4 genes, copy number 5: RNU6-138P, KCNH8, MIR4791, AC061958.1.
- chr3:61,561,569–94,131,832, 273 genes, copy number 5 (broad region; genes not listed).
- chr3:96,566,357–175,810,548, 1,250 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:175,059,361–190,412,138, 288 genes, copy number 5 (broad region; genes not listed).
- chr3:193,144,464–193,593,111, 8 genes, copy number 5: AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1.
- chr7:7,156,934–8,752,961, 26 genes, copy number 5: C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1.
- chr7:10,449,820–23,311,729, 148 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr7:78,017,055–79,453,667, 1 gene, copy number 5 (within-gene range 2–5): MAGI2.
- chr7:78,392,626–78,448,999, 1 gene, copy number 5: AC006043.1.
- chr7:78,939,850–142,619,532, 1,118 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:19,878,555–20,643,448, 33 genes, copy number 5: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4.
- chr16:35,722,268–35,912,516, 26 genes, copy number 5: AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.
- chr20:7,069,614–11,345,855, 53 genes, copy number 5: AL096799.1, LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1.
- chr22:16,572,027–17,779,481, 61 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 761. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
